Somatic mutation profile of tumor specimen TARGET-10-PASIIY-09A (aliquot TARGET-10-PASIIY-09A-01D) from TARGET case TARGET-10-PASIIY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.9 years (2,171 days).
Specimen TARGET-10-PASIIY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da10ff6e-dc4c-4155-a186-c433ad359d7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASIIY-10A (Blood Derived Normal), aliquot TARGET-10-PASIIY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ffda8353-a89c-4ab0-9cc9-7c69cead44d2

The open-access MAF lists 20 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, RNA 3, Silent 2, Nonsense Mutation 2, 3'UTR 2, Frame Shift Ins 2, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.2065C>T p.R689W (on ENST00000281708 / NM_001349798.2; = p.R609W on NM_018315.5) | Missense Mutation (SNP) | VAF 28/54 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55895191, COSV55934968; called by muse, mutect2, varscan2
- ASTN1 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs760958680, COSV56070701; called by muse, mutect2, varscan2
- CTCF | c.1879G>T p.E627* | Nonsense Mutation (SNP) | VAF 23/51 reads (45%) | catalogued as COSV50502270; called by muse, mutect2, varscan2
- MCMDC2 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs769985194, COSV58039608; called by muse, varscan2
- MYB | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs777923027, COSV57196169, COSV57200862; called by muse, mutect2, varscan2
- NOTCH1 | c.4790G>T p.S1597I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1564190486, COSV53061784; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHGC5 | c.2059C>T p.R687C | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as rs777271881, COSV52763713; called by muse, mutect2, varscan2
- RXRA | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs759561054, COSV62684590; called by muse, mutect2, varscan2
- SMARCA4 | c.4454_4455insTGTCC p.I1486Vfs*27 | Frame Shift Ins (INS) | VAF 11/30 reads (37%) | catalogued as COSV60805242; called by mutect2, pindel
- TIGD7 | c.1273G>T p.E425* | Nonsense Mutation (SNP) | VAF 56/128 reads (44%) | catalogued as COSV51916034, COSV51916726; called by muse, mutect2, varscan2
- USP9X | c.7401_7402insAGAA p.A2468Rfs*6 | Frame Shift Ins (INS) | VAF 26/30 reads (87%) | catalogued as COSV61073882; called by mutect2, pindel, varscan2
- ADAM18 | c.2091G>A p.L697= | Silent (SNP) | VAF 4/57 reads (7%) | called by muse, mutect2
- GREB1 | c.3705C>T p.P1235= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as rs748843513; called by muse, mutect2, varscan2
- GPAT4 | c.537-29C>G | Intron (SNP) | VAF 30/66 reads (45%) | called by muse, mutect2, varscan2
- HNRNPCP2 | n.349C>T | RNA (SNP) | VAF 36/116 reads (31%) | called by muse, mutect2, varscan2
- MIR485 | n.20G>A | RNA (SNP) | VAF 36/62 reads (58%) | catalogued as rs759919795; called by muse, mutect2, varscan2
- MST1L | n.986C>T | RNA (SNP) | VAF 7/16 reads (44%) | catalogued as rs1439786568; called by muse, mutect2, varscan2
- PTGR1 | chr9:111603003 G>A | 5'Flank (SNP) | VAF 4/12 reads (33%) | catalogued as rs557625423; called by muse, varscan2
- SH2D3A | c.*5G>A | 3'UTR (SNP) | VAF 14/22 reads (64%) | catalogued as rs1371858653; called by muse, mutect2, varscan2
- ZNF423 | c.*26C>T | 3'UTR (SNP) | VAF 24/54 reads (44%) | catalogued as COSV99280358; called by muse, mutect2, varscan2
